Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A02Y, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A02Y-01A (Primary Tumor).

Diagnosis:

This is material shows a highly to moderately differentiated adenocarcinoma of the colon (colic carcinoma possibly on the basis of a pre-existing tubulovillous adenoma) with infiltration of the muscularis and lymph and blood vessel invasion (pT2, L1, V1), it also shows free resection margins and a free ligature region and free lymph nodes (pN0), a chronic appendicitis with partial scarring and in II) – corresponding to the clinical data – a characteristic Meckel's diverticulum.

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: Cecum (pN CQCF) C18.0 hr 3/30/11

Source: NCI Genomic Data Commons file a032615a-4548-4b4a-9303-001f1c84e94d (TCGA-AA-A02Y.214F632B-B4EE-41CE-A008-B249A9E80269.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).